Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A5A1, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A5A1-01A (Primary Tumor).

[page 1 of 4]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT PELVIC LYMPH NODE:
One lymph node, no tumor present.
- (B) RIGHT PELVIC LYMPH NODE:
Two lymph nodes, no tumor present.
- (C) MULTIPLE EXTRACTIONS:
Multiple teeth, gross diagnosis only.
- (D) RIGHT NEUROVASCULAR BUNDLE:
Supplemental report to follow.
- (E) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.
- (F) PERIURETHRAL TISSUE, LEFT:
Supplemental report to follow.
- (G) PERIURETHRAL TISSUE, RIGHT:
Supplemental report to follow.
- (H) PERIURETHRAL TISSUE, LEFT:
Supplemental report to follow.

ICD-O-3

Path: Adenocarcinoma NOS 8140/3
CGCF Adenocarcinoma
Acinar Type 8550/3

Path: Prostate NOS C61.9
GND 11/18/13

GROSS DESCRIPTION

- (A) LEFT PELVIC LYMPH NODE – The specimen consists of a fragment of fibrofatty tissue measuring 4.0 x 2.5 x 1.0 cm. Embedded within the fibrofatty tissue is a grossly identified lymph node measuring 3.0 x 1.0 x 0.5 cm. The entire lymph node is submitted for frozen section diagnosis.
SECTION CODE: A1-A3, one lymph node sectioned.
*FS/DX: ONE LYMPH NODE, NO TUMOR PRESENT.
- (B) RIGHT PELVIC LYMPH NODE - A fragment of fibrofatty tissue measuring 4.5 x 3.0 x 1.0 cm. Embedded within the fibrofatty tissue is a grossly identified lymph node measuring 2.5 x 1.0 x 0.5 cm. The entire lymph node is submitted for frozen section diagnosis. Also noted is a smaller lymph node measuring 2.0 x 0.5 x 0.5 cm. Frozen section of the lymph nodes are submitted for frozen section diagnosis as follows:
SECTION CODE: B1, B2, one lymph node, bisected; B3, one lymph node.
*FS/DX: TWO LYMPH NODES, NO TUMOR PRESENT.
- (C) MULTIPLE EXTRACTIONS – The specimen consists of six gray-pink teeth ranging in size from 0.8 x 2.0 x 0.5 to 1.0 x 2.5 x 0.8 cm). Three teeth have metallic silver fillings. No other gross abnormalities are identified. The specimen is for gross identification only.
- (D) RIGHT NEUROVASCULAR BUNDLE - Supplemental report to follow.
- (E) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.
- (F) PERIURETHRAL TISSUE, LEFT - Supplemental report to follow.
- (G) PERIURETHRAL TISSUE, RIGHT - Supplemental report to follow.
- (H) PERIURETHRAL TISSUE, LEFT - Supplemental report to follow.

CLINICAL HISTORY

History of prostate cancer.

[page 2 of 4]
[REDACTED]

SNOMED CODES

[REDACTED]

Start of ADDENDUM

[page 3 of 4]
ADDENDUM

DIAGNOSIS

(D) RIGHT NEUROVASCULAR BUNDLE:

Fibroadipose tissue with vascular structures and nerve trunks consistent with neurovascular bundle tissue, no tumor present.

(E) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5). (SEE COMMENT)

CARCINOMA EXTENDING IN MULTIPLE AREAS INTO EXTRAPROSTATIC TISSUE.

CARCINOMA EXTENSIVELY INVOLVING MARGIN OF RESECTION.

CARCINOMA EXTENSIVELY INVOLVING RIGHT AND LEFT SEMINAL VESICLES (INTRAPROSTATIC AND EXTRAPROSTATIC PORTIONS) AND PERIVESICULAR ADIPOSE TISSUE.

CARCINOMA PRESENT WITHIN LOOSE CONNECTIVE TISSUE SURROUNDING EJACULATORY DUCTS (SO-CALLED INVAGINATED EXTRAPROSTATIC SPACE).

TUMOR PRESENT WITHIN ENDOTHELIUM LINED SPACES WITHIN THE PROSTATE AND IN THE INVAGINATED EXTRAPROSTATIC SPACE.

(F) PERIURETHRAL TISSUE, LEFT:

Skeletal muscle and fibromuscular tissue, no tumor present.

(G) PERIURETHRAL TISSUE, RIGHT:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5), EXTENSIVELY INVOLVING FIBROMUSCULAR TISSUE.

No prostatic glands present.

(H) PERIURETHRAL TISSUE, LEFT:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5) INVOLVING FIBROMUSCULAR TISSUE AND FOCALLY SKELETAL MUSCLE.

COMMENT

The prostate gland contains a single focus of prostatic adenocarcinoma. The tumor occupies approximately 70% of the prostatic volume and measures 3.9 x 3.8 cm in the largest cross sectional dimension and it is present in the two cross sections of the prostate and extensively in the apex and base regions. The tumor exhibits extraprostatic extension in multiple areas including the left anterior prostatic surface, anterior apex, bladder neck and left superior neurovascular bundle region. Tumor extensively involves the margin of resection including anterior apex (added length 26.0 mm) and anterior bladder neck (added length, 10.0 mm). Tumor extensively involves both seminal vesicles including the intra and extraprostatic portions as well as perivesicular soft tissue. Immunoperoxidase studies for chromogranin and synaptophysin demonstrate focally rare immunoreactive cells, supporting the presence of cells with neuroendocrine differentiation. The amount of immunoreactive cells is within the spectrum observed in high grade carcinomas. The stains for PSA and PAP show diffuse strong immunoreactivity. The tumor exhibits focal mucinous differentiation.

Pu TSS, mucinous

% = < 5%

for

[page 4 of 4]
[REDACTED]

GROSS DESCRIPTION

(D) RIGHT NEUROVASCULAR BUNDLE – An irregular fragment of tan-gray tissue(2.0 x 1.5 x 0.4 cm). Submitted in toto in D.

(E) PROSTATE AND SEMINAL VESICLES - A specimen consisting in a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.0 x 3.7 x 3.5 cm, 38 grams, post-fixation) has the usual shape. The soft tissue present along the right and left posterolateral aspects of the prostate appears symmetrical. A firm nodule is palpated on the entire left side of the prostate. Serial cross sections after fixation demonstrate a firm area in the left peripheral zone of the first cross section. In the anterior surface of the prostate there is an area of surface disruption which exposes a surface that is not the true margin. This area is inked blue.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: E1, E2, right seminal vesicles and right vas deferens from the base towards the tip entirely submitted; E3, E4, left seminal vesicle and left vas deferens from the base towards the tip, entirely submitted; E5, prostatic base, right border; E6, E7, prostatic base, right posterior border; E8-E17, prostatic base, central portion; E18, E19, prostatic base left border; E20-E23, prostatic base, left posterior border; E24-E26, apex anterior; E27, E28, apex left; E29-E31, apex posterior; E32, E33, apex right; E34, detached portions of margin of resection according to specimen radiograph E35-E42, sections of the two cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow, and posterior surface in black. Blue ink (E24-E26) and orange (E42) denotes surfaces which do not represent the true margin of resection.

(F) PERIURETHRAL TISSUE, LEFT – An irregular fragment of tan-gray tissue (1.0 x 0.3 x 0.1 cm). Submitted in toto in F.

(G) PERIURETHRAL TISSUE, RIGHT – An irregular fragment of tan-gray tissue (0.4 x 0.4 x 0.1 cm). Submitted in toto in G.

(H) PERIURETHRAL TISSUE, LEFT, CLIP AT MARGIN – An irregular fragment of tan-gray tissue (1.0 x 0.6 x 0.1 cm). Submitted in toto in H.

SNOMED CODES

[REDACTED]

-----END OF REPORT-----

Criteria	lw 2/2/13	Yes	No
Diagnostic Discrepancy			✓
HPV Discrepancy			✓

Source: NCI Genomic Data Commons file 68109b0c-15d7-4d39-9cab-4e57771cef21 (TCGA-KK-A5A1.DF56D103-963E-4C23-9DB8-1333AFF418CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).